Somatic mutation profile of tumor specimen TCGA-BJ-A18Z-01A (aliquot TCGA-BJ-A18Z-01A-21D-A13W-08) from TCGA case TCGA-BJ-A18Z, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 58.9 years (21,519 days).
Specimen TCGA-BJ-A18Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd43ef35-c29b-461a-9e26-266a79a4fb77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A18Z-10A (Blood Derived Normal), aliquot TCGA-BJ-A18Z-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73a1e2f1-d6fa-439e-ac70-099a2fcac599

The open-access MAF lists 15 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 13, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AMPD3 | c.1534G>A p.E512K (on ENST00000396553 / NM_001025389.2; = p.E521K on NM_000480.3) | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.095); catalogued as COSV67332118; called by muse, mutect2
- AOX1 | c.493T>C p.C165R | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV65983568; called by muse, mutect2, varscan2
- ARHGEF4 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV58125066, COSV58128250; called by muse, mutect2
- BECN1 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59312674; called by muse, mutect2
- GSTA2 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.312); catalogued as COSV72415432; called by muse, mutect2, varscan2
- MAP3K3 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV62281505; called by muse, mutect2, varscan2
- MEGF11 | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV56559161; called by muse, mutect2, varscan2
- MUSK | c.2549C>G p.T850S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV51893908; called by muse, mutect2, varscan2
- NIBAN2 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 82/388 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64825303; called by muse, mutect2, varscan2
- OR11G2 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100640035, COSV62132965; called by muse, mutect2, varscan2
- OR14C36 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.089); catalogued as rs776779347, COSV100507658, COSV58602490; called by muse, mutect2
- PLCG1 | c.3029G>A p.R1010H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868557349, COSV54818084, COSV54822887; called by muse, mutect2
- WNK2 | c.6368G>A p.S2123N (on ENST00000297954 / NM_001282394.1; = p.S2086N on NM_006648.3) | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52956759; called by muse, mutect2
- LGI1 | c.1095C>T p.N365= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs934556455, COSV65059009; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
